Surgical pathology report (de-identified scan), TCGA case TCGA-06-0410, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0410-01A (Primary Tumor).

Patient Name: MRN: Birth Date: Sex: Female Room/Bed:

PATIENT NAME:
SP. NO.:
ORDERING PHYSICIAN:

AGE/SEX: F

PATH. NO:

NAME:

MED. REC. NO:

AGE/SEX:

RECEIVE DATE:

PHYSICIAN:

PATHOLOGICAL DIAGNOSIS:

BRAIN, SITE NOT SPECIFIED, BIOPSY: GLIOBLASTOMA MULTIFORME. MIB-1
INDEX OF 30-40%. SEE DESCRIPTIONS AND COMMENT.

Operation/Specimen: Brain.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY: Specimen 1 received in fresh state for a frozen
section, the specimen consists of several small fragments of friable
reddish-brown, somewhat gelatinous tissue measuring 0.7 cm. across in
the aggregate. Touch imprint and smears obtained. Tissue entirely
submitted in cassette 1.

INTRAOPERATIVE DIAGNOSIS: Brain: Malignant glioma.

Specimen 2 received suspended in saline for permanent sections, the
specimen consists of a 0.9 cm. across and several smaller pieces
measuring up to 0.3 cm. in the aggregate, of grayish-white gelatinous
tissue. Specimen submitted in its entirety in cassette 2.

MICROSCOPIC: The sections from specimens 1 and 2 contain portions of a
neoplastic proliferation of glial cells with marked features of
anaplasia: severe nuclear pleomorphism, frequent mitotic figures,
vascular/endothelial proliferation, and focal areas of necrosis. The
tumor is diffusely infiltrating the cerebral cortex.

Immunoperoxidase stains for GFAP and MIB-1 are performed. The GFAP
demonstrates the astroglial nature of the neoplasm. With the MIB-1 a
30-40% labeling index is determined.

COMMENT: The lesion is a glioblastoma multiforme with a high MIB-1
labeling index.

T ISSUE COMMITTEE CODE:
L LING CODES:

Source: NCI Genomic Data Commons file 60a61ff5-09cb-4b66-a66b-8bd27ca06670 (TCGA-06-0410.BD01E24E-0773-4BA9-A505-6EFEFD1B3B92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).